Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A4XJ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A4XJ-01A (Primary Tumor).

Gross Description: In bladder, there are an invasive tumor, ill - margins with 3.5x3x2cm in size, soft and gray surface.

Microscopic Description: Transitional cells are hyperplastic. Tumor cells arrange to form nests or groups or cords one by one or sheets with central necrosis. Tumor cells have moderate and eosinophilic cytoplasm. Nuclei are enlarged and variability in shape and size, very irregular nuclear membranes, nucleoli and abnormal chromatin patterns. Mitoses are common. Tumor invades in fat tissue

Diagnosis Details: Infiltrating urothelial carcinoma, High-grade, infiltrating fat tissue

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Cystectomy

Tumor site: Bladder

Tumor size: 3.5 x 3 x 2 cm

Tumor features: None specified

Histologic type: Transitional cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Perivesical tissue (microscopic)

Lymph nodes: Not specified

Lymphatic invasion: Absent

Venous invasion: Absent

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Invades fat tissue and muscle, Non-papillary

Comments: Extracapsular extension: Yes, focal; Anatomic organ subdivision: Wall, NOS

1CD-0-3

Carcinoma, transitional cell, NOS 8/20/3
Site: bladder, NOS C67.9

W
10/23/12

Distant Synchronous Primary Malignancy		

W
10/23/12

Source: NCI Genomic Data Commons file d5a48ab8-5204-4b04-b39b-6bad62842a4c (TCGA-E7-A4XJ.BF8490C7-4535-4EFF-9785-887C7B58CC75.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).